Somatic mutation profile of tumor specimen TCGA-F4-6463-01A (aliquot TCGA-F4-6463-01A-11D-1719-10) from TCGA case TCGA-F4-6463, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Transverse colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 51.5 years (18,804 days).
Specimen TCGA-F4-6463-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b83e1471-a7f2-4130-a9cb-19ea49f297b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F4-6463-10A (Blood Derived Normal), aliquot TCGA-F4-6463-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/221b6970-4e01-41bd-a4a2-b10d23baf9de

The open-access MAF lists 84 somatic variants for this specimen: 59 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 23, Nonsense Mutation 2, Frame Shift Del 2, Frame Shift Ins 2, 3'UTR 1, Splice Region 1, In Frame Del 1, Splice Site 1, In Frame Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4473dup p.A1492Cfs*22 | Frame Shift Ins (INS) | VAF 26/142 reads (18%) | catalogued as rs398123122, COSV57345867, COSV99964369, COSV99971373; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 134/268 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, varscan2
- SCN1A | c.2593C>T p.R865* (on ENST00000303395 / NM_001202435.3; = p.R854* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 43/196 reads (22%) | catalogued as rs794726697, CM024301, CM117762, COSV57676304, COSV57682309; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AFF4 | c.745A>G p.M249V | Missense Mutation (SNP) | VAF 153/500 reads (31%) | SIFT tolerated (1); PolyPhen probably damaging (0.926); catalogued as rs200807688, COSV54800262; called by muse, mutect2, varscan2
- APOBEC3A | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 77/242 reads (32%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.733); catalogued as COSV50779490; called by muse, mutect2, varscan2
- ARHGAP33 | c.2608G>A p.G870S | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs766133322, COSV50159225; called by muse, mutect2, varscan2
- ATP1B2 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.117); catalogued as rs755969286, COSV51515055; called by muse, mutect2, varscan2
- BACH2 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs768854192, COSV57610512, COSV57611676; called by muse, mutect2, varscan2
- CAPZA2 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 82/314 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV63266832; called by muse, mutect2, varscan2
- CSNK1G2 | c.404G>T p.R135L | Missense Mutation (SNP) | VAF 89/246 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV55337784; called by muse, mutect2, varscan2
- CYTL1 | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 189/566 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.922); catalogued as rs200085707, COSV57036803; called by muse, mutect2, varscan2
- DCHS1 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs962936794, COSV55038672; called by muse, mutect2, varscan2
- ERBB4 | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 89/313 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1463950609, COSV53593488; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1378T>A p.S460T | Missense Mutation (SNP) | VAF 68/282 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.478); catalogued as rs200469764, COSV58559344; called by muse, mutect2, varscan2
- FZD9 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV60671571; called by muse, mutect2
- FZR1 | c.1466T>A p.L489H (on ENST00000395095 / NM_001136198.1; = p.L486H on NM_016263.4) | Missense Mutation (SNP) | VAF 70/270 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58054184; called by muse, mutect2, varscan2
- GLUD2 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as COSV100046724; called by muse, mutect2
- GRK4 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as rs1434192900, COSV100055088; called by muse, mutect2
- HCAR3 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 67/161 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as rs752429527, COSV63677003, COSV63678347; called by muse, mutect2, varscan2
- HIPK4 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 49/223 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs774483576, COSV52520701; called by muse, mutect2, varscan2
- IL31RA | c.1353C>T p.G451= | Splice Region (SNP) | VAF 36/145 reads (25%) | catalogued as rs755336880, COSV51683619; called by muse, mutect2, varscan2
- KANSL1 | c.1290-1G>A p.X430_splice | Splice Site (SNP) | VAF 29/154 reads (19%) | catalogued as COSV52274698; called by muse, mutect2, varscan2
- KDM6A | c.3579G>A p.W1193* | Nonsense Mutation (SNP) | VAF 118/224 reads (53%) | catalogued as COSV65046872; called by muse, mutect2, varscan2
- KIAA0232 | c.1851C>G p.I617M | Missense Mutation (SNP) | VAF 62/200 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as COSV56929845; called by muse, mutect2, varscan2
- KIF1A | c.1951C>T p.R651C | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs755461108, COSV57503222; called by muse, mutect2, varscan2
- KMT2D | c.16361G>A p.R5454Q | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56434564; called by muse, mutect2, varscan2
- LAMA2 | c.948T>G p.D316E | Missense Mutation (SNP) | VAF 56/179 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV70356122; called by muse, mutect2, varscan2
- LENG8 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs199812836, COSV58729121; called by muse, mutect2, varscan2
- LRP1 | c.11257C>T p.R3753C | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs771090395, COSV54527892; called by muse, mutect2, varscan2
- LRRN4 | c.697C>T p.L233F | Missense Mutation (SNP) | VAF 68/274 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV101125487, COSV66646437; called by muse, mutect2, varscan2
- MACO1 | c.197A>G p.Y66C | Missense Mutation (SNP) | VAF 65/213 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776716811, COSV65478570; called by muse, mutect2, varscan2
- MAGEB3 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 150/274 reads (55%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.677); catalogued as COSV100854842, COSV64397818; called by muse, mutect2, varscan2
- MAGI2 | c.2527G>A p.D843N | Missense Mutation (SNP) | VAF 119/459 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs745367148, COSV62664020; called by muse, mutect2, varscan2
- MAP2K7 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67607626; called by muse, mutect2
- MSH3 | c.2359G>A p.E787K | Missense Mutation (SNP) | VAF 33/257 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.982); catalogued as COSV54166031, COSV54166930; called by muse, mutect2, varscan2
- MYEF2 | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 30/463 reads (6%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.997); catalogued as COSV51051037; called by muse, mutect2
- MYH2 | c.1535C>T p.T512M | Missense Mutation (SNP) | VAF 76/286 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.595); catalogued as rs376478405, COSV55435392; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYOZ1 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.155); catalogued as rs756180269, COSV63771680; called by muse, mutect2, varscan2
- NOC4L | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs994452973, COSV57960314; called by muse, mutect2, varscan2
- PCDHA3 | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 89/317 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.909); catalogued as rs1274408864, COSV63542512; called by muse, mutect2, varscan2
- PDE1C | c.820G>A p.G274R | Missense Mutation (SNP) | VAF 94/311 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs559775895, COSV58503981, COSV58516090; called by muse, mutect2, varscan2
- PELP1 | c.2814A>T p.E938D | Missense Mutation (SNP) | VAF 86/309 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.943); catalogued as COSV52592983; called by muse, mutect2, varscan2
- PLCG2 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs750403828, COSV63877238; called by muse, mutect2, varscan2
- PRL | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 35/428 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.078); catalogued as rs764728645, COSV100123252, COSV60593577; called by muse, mutect2
- PTPRZ1 | c.3575A>G p.D1192G | Missense Mutation (SNP) | VAF 90/311 reads (29%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); catalogued as COSV66446450; called by muse, mutect2, varscan2
- PWWP3A | c.352C>T p.R118W (on ENST00000627377; = p.R117W on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs189340337, COSV60905506; called by muse, mutect2, varscan2
- RPL24 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 139/530 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); catalogued as COSV57247189; called by muse, mutect2, varscan2
- SLC18A3 | c.160G>A p.V54M | Missense Mutation (SNP) | VAF 60/264 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60334185; called by muse, mutect2, varscan2
- SMC5 | c.2927A>G p.K976R | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV63195818; called by muse, mutect2, varscan2
- SOS1 | c.239A>G p.H80R | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as COSV67677867; called by muse, mutect2, varscan2
- SS18L1 | c.143C>T p.T48M | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.369); catalogued as rs746253864, COSV59214066; called by muse, mutect2, varscan2
- TRRAP | c.8851G>A p.A2951T (on ENST00000359863 / NM_001244580.1; = p.A2933T on NM_003496.3) | Missense Mutation (SNP) | VAF 78/258 reads (30%) | SIFT tolerated (0.88); PolyPhen benign (0.111); catalogued as rs537483764, COSV62840522; called by muse, mutect2, varscan2
- UNC13C | c.6448G>A p.G2150R | Missense Mutation (SNP) | VAF 95/321 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs753460509, COSV52876360; called by muse, mutect2, varscan2
- WWC1 | c.2900G>A p.S967N | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54659321; called by muse, mutect2, varscan2
- KAT14 | c.423_425dup p.R142dup | In Frame Ins (INS) | VAF 110/455 reads (24%) | called by mutect2, pindel, varscan2
- OR8K1 | c.532_545del p.N178Ffs*4 | Frame Shift Del (DEL) | VAF 64/294 reads (22%) | called by mutect2, pindel, varscan2
- SDHAF2 | c.227dup p.R77Efs*11 | Frame Shift Ins (INS) | VAF 18/150 reads (12%) | called by mutect2, pindel, varscan2
- SEMA4D | c.1381_1383del p.I461del | In Frame Del (DEL) | VAF 37/177 reads (21%) | called by pindel, varscan2
- TTN | c.27077_27080del p.D9026Afs*9 (on ENST00000591111; = p.D8099Afs*9 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 65/260 reads (25%) | called by mutect2, pindel, varscan2
- BEGAIN | c.735T>C p.P245= | Silent (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- CADPS2 | c.3345C>T p.I1115= | Silent (SNP) | VAF 53/218 reads (24%) | catalogued as rs572495018, COSV57388329; called by muse, mutect2, varscan2
- CHD5 | c.3399C>T p.R1133= | Silent (SNP) | VAF 37/148 reads (25%) | catalogued as rs773168274, COSV52426327; called by muse, mutect2, varscan2
- CSMD2 | c.6057C>T p.H2019= | Silent (SNP) | VAF 82/266 reads (31%) | catalogued as rs377127395; called by muse, mutect2, varscan2
- DEGS2 | c.822G>A p.P274= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as rs374265570; called by muse, mutect2, varscan2
- DLGAP2 | c.2040C>T p.A680= | Silent (SNP) | VAF 55/170 reads (32%) | catalogued as rs761958591, COSV70098267; called by muse, mutect2, varscan2
- ELF1 | c.1293G>A p.V431= | Silent (SNP) | VAF 22/259 reads (8%) | catalogued as COSV53503287; called by muse, mutect2
- FAT3 | c.13176C>T p.S4392= | Silent (SNP) | VAF 56/242 reads (23%) | catalogued as rs759657516, COSV53160333; called by muse, mutect2, varscan2
- GET3 | c.186C>A p.S62= | Silent (SNP) | VAF 44/147 reads (30%) | catalogued as COSV54407666; called by muse, mutect2, varscan2
- GTF2IRD2 | c.1791G>A p.S597= | Silent (SNP) | VAF 160/940 reads (17%) | catalogued as rs879974784, COSV63100970; called by muse, mutect2
- IPO9 | c.2952C>T p.Y984= | Silent (SNP) | VAF 61/233 reads (26%) | catalogued as rs750181885, COSV64236494; called by muse, mutect2, varscan2
- LIPH | c.636C>A p.G212= | Silent (SNP) | VAF 28/384 reads (7%) | catalogued as COSV56186634; called by muse, mutect2
- MUC16 | c.24288G>A p.T8096= | Silent (SNP) | VAF 144/495 reads (29%) | catalogued as rs1410019394, COSV101201954; called by muse, mutect2, varscan2
- OR5J2 | c.207G>A p.V69= | Silent (SNP) | VAF 49/404 reads (12%) | catalogued as rs1349070516, COSV56623474; called by muse, mutect2, varscan2
- PCDHA9 | c.171G>A p.A57= | Silent (SNP) | VAF 108/336 reads (32%) | catalogued as COSV65332031, COSV65334297; called by muse, mutect2, varscan2
- POLN | c.2205G>A p.V735= | Silent (SNP) | VAF 96/276 reads (35%) | catalogued as COSV67027934; called by muse, mutect2, varscan2
- PXDNL | c.3438A>G p.R1146= | Silent (SNP) | VAF 12/246 reads (5%) | catalogued as COSV100686794, COSV62496506; called by muse, mutect2
- RPL3L | c.741C>T p.G247= | Silent (SNP) | VAF 33/122 reads (27%) | catalogued as COSV51908660; called by muse, mutect2, varscan2
- SF3B3 | c.660G>A p.V220= | Silent (SNP) | VAF 26/338 reads (8%) | catalogued as COSV100210303, COSV56787889; called by muse, mutect2
- SLC26A7 | c.903G>A p.P301= | Silent (SNP) | VAF 40/514 reads (8%) | catalogued as rs1011789965, COSV52593554, COSV99404524; called by muse, mutect2
- STAT5B | c.1203C>T p.C401= | Silent (SNP) | VAF 53/237 reads (22%) | catalogued as rs200710135, COSV53181371; ClinVar: likely benign; called by muse, mutect2, varscan2
- UBQLN3 | c.138G>T p.L46= | Silent (SNP) | VAF 92/318 reads (29%) | catalogued as COSV61166043; called by muse, mutect2, varscan2
- WNK1 | c.1296C>T p.Y432= | Silent (SNP) | VAF 121/430 reads (28%) | catalogued as COSV60046554; called by muse, mutect2, varscan2
- CPLANE1 | c.*2463C>T | 3'UTR (SNP) | VAF 49/184 reads (27%) | catalogued as rs551925061, COSV57075846; called by muse, mutect2, varscan2
- NDUFV3 | c.170-5253G>A | Intron (SNP) | VAF 23/100 reads (23%) | catalogued as rs373783778, COSV61087745; called by muse, mutect2, varscan2
